Somatic mutation profile of tumor specimen MP2PRT-PAUPCE-TMP1-A (aliquot MP2PRT-PAUPCE-TMP1-A-1-0-D-A81P-36) from MP2PRT case MP2PRT-PAUPCE, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: male; Vital status: Alive; Primary diagnosis: Common precursor B ALL; Tissue or organ of origin: Bone marrow; Age at diagnosis: 5.5 years (1,992 days).
Specimen MP2PRT-PAUPCE-TMP1-A: Sample type: Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Whole Bone Marrow; Biospecimen anatomic site: Bone Marrow; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) aad46b2a-13b6-4436-bc9d-7e3e0c8ffabb.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MP2PRT-PAUPCE-NB1-A (Blood Derived Cancer - Peripheral Blood, Post-treatment; tissue type Normal — post-treatment blood used as the germline comparator), aliquot MP2PRT-PAUPCE-NB1-A-1-0-D-A81P-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/b00c24ba-d549-493b-b753-4e3f2dc3b99d

The open-access MAF lists 20 somatic variants for this specimen: 13 protein-altering or splice-affecting, 6 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 11, Silent 6, 3'Flank 1, Splice Region 1, In Frame Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KRAS | c.38G>A p.G13D | Missense Mutation (SNP) | VAF 37/323 reads (11%) | hotspot (GDC flag); SIFT deleterious (0.04); PolyPhen benign (0.44); catalogued as rs112445441, CM125166, COSV55497357, COSV55497388, COSV55522580; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- PTPN11 | c.1508G>C p.G503A | Missense Mutation (SNP) | VAF 79/356 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.957); catalogued as rs397507546, CM086897, CM115675, CM1314033, COSV61004973, COSV61005158, COSV61008174; ClinVar: pathogenic; called by muse, mutect2, varscan2
- HYAL4 | c.826C>T p.R276C | Missense Mutation (SNP) | VAF 39/298 reads (13%) | SIFT deleterious (0.01); PolyPhen benign (0.019); catalogued as rs755669947, COSV56138003; called by muse, mutect2, varscan2
- MXD3 | c.506-7C>T | Splice Region (SNP) | VAF 324/644 reads (50%) | catalogued as rs766303761; called by muse, mutect2, varscan2
- OR5I1 | c.752C>T p.T251M | Missense Mutation (SNP) | VAF 31/283 reads (11%) | SIFT tolerated (0.06); PolyPhen benign (0.218); catalogued as rs913931606, COSV56885185; called by muse, mutect2, varscan2
- SORBS2 | c.1693G>A p.A565T | Missense Mutation (SNP) | VAF 60/348 reads (17%) | SIFT tolerated (0.38); PolyPhen benign (0); catalogued as rs200642160; called by muse, mutect2, varscan2
- TXNRD2 | c.1408G>A p.A470T | Missense Mutation (SNP) | VAF 14/468 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs931478209, COSV68691942; called by muse, mutect2
- UGT1A10 | c.392G>A p.R131Q | Missense Mutation (SNP) | VAF 12/144 reads (8%) | SIFT tolerated (0.32); PolyPhen benign (0.003); catalogued as rs777228086, COSV60838184; called by muse, mutect2
- LRIG3 | c.847C>A p.L283I | Missense Mutation (SNP) | VAF 42/343 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.937); called by muse, mutect2, varscan2
- POLR3B | c.1138T>A p.F380I | Missense Mutation (SNP) | VAF 89/182 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.934); called by muse, mutect2, varscan2
- RNF166 | c.505T>G p.C169G | Missense Mutation (SNP) | VAF 147/370 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- XCL1 | c.331A>T p.T111S | Missense Mutation (SNP) | VAF 39/317 reads (12%) | SIFT tolerated (0.11); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- ZBTB2 | c.54_55insAGGCGA p.R18_E19insRR | In Frame Ins (INS) | VAF 122/552 reads (22%) | called by mutect2, pindel, varscan2
- ABCA9 | c.4503T>C p.C1501= | Silent (SNP) | VAF 85/251 reads (34%) | called by muse, mutect2, varscan2
- ARAP1 | c.96G>C p.L32= | Silent (SNP) | VAF 27/617 reads (4%) | called by muse, mutect2
- DSG3 | c.285G>A p.P95= | Silent (SNP) | VAF 54/592 reads (9%) | catalogued as rs577530234, COSV57125080; called by muse, mutect2
- ITGA2B | c.1185C>T p.G395= | Silent (SNP) | VAF 159/487 reads (33%) | catalogued as rs147634553; called by muse, mutect2, varscan2
- PCDHB5 | c.537T>C p.H179= | Silent (SNP) | VAF 14/380 reads (4%) | called by muse, mutect2
- SDK1 | c.1479C>T p.D493= | Silent (SNP) | VAF 137/302 reads (45%) | catalogued as rs149234557; called by muse, mutect2, varscan2
- MYL3 | chr3:46834071 C>T | 3'Flank (SNP) | VAF 67/628 reads (11%) | called by muse, mutect2, varscan2
